Somatic mutation profile of tumor specimen C3N-03430-02 (aliquot CPT0226650007) from CPTAC case C3N-03430, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 54.6 years (19,939 days).
Specimen C3N-03430-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c9778f6a-7780-4481-b648-d1404e5aa19e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03430-31 (Blood Derived Normal), aliquot CPT0226670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7360322b-5b78-438e-8f0e-b416944fccb6

The open-access MAF lists 92 somatic variants for this specimen: 65 protein-altering or splice-affecting, 16 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 16, Intron 4, Nonsense Mutation 3, 3'UTR 2, Frame Shift Del 2, 5'UTR 2, Splice Region 2, Frame Shift Ins 1, Nonstop Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 207/735 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD62 | c.1121C>T p.T374M | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs192217310; called by muse, mutect2
- ATG2A | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 34/438 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs756230306; called by muse, mutect2
- ATRNL1 | c.2441G>A p.R814H | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs781892443, COSV58075293; called by muse, mutect2, varscan2
- C3 | c.3466G>A p.D1156N | Missense Mutation (SNP) | VAF 89/857 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.28); catalogued as CM153562, COSV55583658; called by muse, mutect2, varscan2
- CNTNAP1 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 92/565 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs148181656; called by muse, mutect2, varscan2
- DPP8 | c.1301C>T p.T434M (on ENST00000341861 / NM_001320875.2; = p.T418M on NM_017743.6) | Missense Mutation (SNP) | VAF 37/409 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as rs758585687; called by muse, mutect2
- DYSF | c.3199G>A p.E1067K | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.939); catalogued as rs1252415299; called by muse, mutect2
- EPHA2 | c.203C>A p.S68Y | Missense Mutation (SNP) | VAF 142/766 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV64452307; called by muse, mutect2, varscan2
- ERBB4 | c.1981C>A p.L661I | Missense Mutation (SNP) | VAF 154/854 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV53544464; called by muse, mutect2, varscan2
- FLG | c.5734A>T p.R1912W | Missense Mutation (SNP) | VAF 122/1559 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.97); catalogued as COSV64244149; called by muse, mutect2
- GJB6 | c.53C>A p.T18N | Missense Mutation (SNP) | VAF 110/1236 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53833227; called by muse, mutect2
- GLI3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 46/502 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs750890677, COSV67889940; called by muse, mutect2
- IVL | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100908206; called by muse, mutect2
- LRFN2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs367755986; called by muse, mutect2, varscan2
- MAGEB1 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.273); catalogued as rs200931248, COSV66775637; called by muse, mutect2, varscan2
- MEGF6 | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs746964214; called by muse, mutect2, varscan2
- OR5H2 | c.718A>G p.R240G | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.097); catalogued as rs745774293; called by muse, mutect2
- SIX2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 82/739 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57390105, COSV57391892; called by muse, mutect2, varscan2
- SPSB4 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs374257422; called by muse, mutect2, varscan2
- TASOR2 | c.3977C>T p.P1326L | Missense Mutation (SNP) | VAF 155/468 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs564549297; called by muse, mutect2, varscan2
- TTN | c.75931G>A p.V25311I (on ENST00000591111; = p.V17887I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/401 reads (8%) | PolyPhen benign (0); catalogued as rs371362606; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2
- UNC13A | c.2497G>A p.V833M | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs779581085, COSV53208124; called by muse, mutect2, varscan2
- UNC80 | c.839T>C p.I280T | Missense Mutation (SNP) | VAF 47/489 reads (10%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); catalogued as rs749870075; called by muse, mutect2
- ZNF43 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 60/797 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as rs771611737; called by muse, mutect2
- ZNF641 | c.923T>A p.I308N | Missense Mutation (SNP) | VAF 140/794 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV56391133; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3823A>G p.S1275G | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ATOH1 | c.580_584delinsG p.K194Gfs*108 | Frame Shift Del (DEL) | VAF 53/558 reads (9%) | called by pindel, varscan2*
- CCER1 | c.1152A>T p.L384F | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2
- CLEC14A | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 52/751 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); called by muse, mutect2
- CMTM5 | c.576T>G p.V192= (on ENST00000339180 / NM_001288746.2; = p.V125= on NM_138460.3) | Splice Region (SNP) | VAF 23/289 reads (8%) | called by muse, mutect2
- DCAF12L2 | c.152T>A p.L51Q | Missense Mutation (SNP) | VAF 70/736 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- DRAP1 | c.58A>C p.I20L | Missense Mutation (SNP) | VAF 159/854 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ERVV-2 | c.1274A>T p.D425V | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.795); called by muse, mutect2
- FAT4 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.92); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- FBN1 | c.65G>A p.S22N | Missense Mutation (SNP) | VAF 85/1085 reads (8%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.58); called by muse, mutect2
- GRM6 | c.1228G>A p.A410T | Missense Mutation (SNP) | VAF 116/1295 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2
- HECTD4 | c.10517_10518del p.S3506Cfs*93 | Frame Shift Del (DEL) | VAF 52/342 reads (15%) | called by pindel, varscan2
- HNRNPA2B1 | c.904G>C p.D302H (on ENST00000354667 / NM_031243.3; = p.D290H on NM_002137.4) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); called by muse, mutect2
- HSPA14 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 197/550 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- HTR4 | c.153-2A>T p.X51_splice | Splice Site (SNP) | VAF 40/341 reads (12%) | called by muse, mutect2
- IRS4 | c.2618C>T p.P873L | Missense Mutation (SNP) | VAF 93/878 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRX2 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 80/1024 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LTBP4 | c.4160G>C p.C1387S (on ENST00000308370 / NM_001042544.1; = p.C1350S on NM_003573.2) | Missense Mutation (SNP) | VAF 143/687 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MANEA | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MFAP3 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 44/692 reads (6%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.009); called by muse, mutect2
- MTCL1 | c.4994_4996dup p.C1665_L1666insR (on ENST00000306329 / NM_001378206.1; = p.C1346_L1347insR on NM_015210.4) | In Frame Ins (INS) | VAF 21/189 reads (11%) | called by mutect2, pindel, varscan2
- NCOA6 | c.4942C>T p.Q1648* | Nonsense Mutation (SNP) | VAF 64/435 reads (15%) | called by muse, mutect2, varscan2
- NRXN3 | c.756A>C p.Q252H | Missense Mutation (SNP) | VAF 44/437 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- OR4D11 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 52/566 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- OR52A1 | c.437T>G p.I146R | Missense Mutation (SNP) | VAF 37/411 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.151); called by muse, mutect2
- PLA2G6 | c.1592-8G>A | Splice Region (SNP) | VAF 27/277 reads (10%) | called by muse, mutect2
- PTPRZ1 | c.435A>C p.E145D | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- RTF1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SLC5A2 | c.751A>T p.I251F | Missense Mutation (SNP) | VAF 101/1226 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- SMN1 | c.877_*3del | Nonstop Mutation (DEL) | VAF 62/526 reads (12%) | called by mutect2, varscan2
- SPRY1 | c.952_953insTTTAC p.P318Lfs*60 | Frame Shift Ins (INS) | VAF 22/143 reads (15%) | called by mutect2, pindel
- SUGP2 | c.128T>G p.L43* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | called by muse, mutect2
- TDRD15 | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- TET1 | c.2858T>C p.L953P | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TTN | c.81104T>G p.L27035R (on ENST00000591111; = p.L19611R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/217 reads (6%) | PolyPhen possibly damaging (0.894); called by muse, mutect2
- VANGL2 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF214 | c.746G>A p.C249Y | Missense Mutation (SNP) | VAF 23/323 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.021); called by muse, mutect2
- ZNF555 | c.361G>T p.G121* | Nonsense Mutation (SNP) | VAF 82/606 reads (14%) | called by muse, mutect2, varscan2
- ZNF91 | c.400G>T p.V134L | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.084); called by muse, mutect2
- BAHCC1 | c.7218C>T p.A2406= | Silent (SNP) | VAF 56/220 reads (25%) | catalogued as rs782067875; called by muse, mutect2, varscan2
- CCER1 | c.558G>A p.P186= | Silent (SNP) | VAF 48/474 reads (10%) | catalogued as rs1445351588; called by muse, mutect2, varscan2
- CUX1 | c.3990G>A p.A1330= | Silent (SNP) | VAF 60/672 reads (9%) | catalogued as rs782420178; called by muse, mutect2
- EHMT2 | c.2082G>A p.Q694= | Silent (SNP) | VAF 70/745 reads (9%) | catalogued as COSV64997676; called by muse, mutect2
- KCNIP4 | c.144G>A p.T48= | Silent (SNP) | VAF 62/754 reads (8%) | catalogued as rs368526954, COSV62850148; called by muse, mutect2
- NEB | c.1521C>T p.D507= | Silent (SNP) | VAF 24/425 reads (6%) | catalogued as COSV51434554; called by muse, mutect2
- NEFH | c.798C>T p.D266= | Silent (SNP) | VAF 131/668 reads (20%) | catalogued as rs571252099; called by muse, mutect2, varscan2
- PRAG1 | c.4050G>A p.T1350= | Silent (SNP) | VAF 154/847 reads (18%) | catalogued as rs1303368510, COSV100422055; called by muse, mutect2, varscan2
- SEMA5A | c.2601T>C p.S867= | Silent (SNP) | VAF 42/572 reads (7%) | catalogued as COSV101227431; called by muse, mutect2
- SERPINA12 | c.756C>T p.D252= | Silent (SNP) | VAF 61/386 reads (16%) | catalogued as rs761146045; called by muse, mutect2, varscan2
- SIGLEC10 | c.1638G>A p.T546= | Silent (SNP) | VAF 80/617 reads (13%) | catalogued as rs201661934, COSV59482899; called by muse, mutect2, varscan2
- SLITRK2 | c.2043C>T p.D681= | Silent (SNP) | VAF 43/625 reads (7%) | catalogued as rs182696674, COSV59425016; called by muse, mutect2
- ST6GAL2 | c.1548G>A p.A516= | Silent (SNP) | VAF 52/375 reads (14%) | catalogued as rs764850258, COSV62416323; called by muse, mutect2, varscan2
- YLPM1 | c.4212A>G p.R1404= | Silent (SNP) | VAF 70/360 reads (19%) | called by muse, mutect2, varscan2
- ZHX1 | c.1026T>C p.S342= | Silent (SNP) | VAF 94/505 reads (19%) | catalogued as rs1563809488; called by muse, mutect2, varscan2
- ZNF571 | c.363T>C p.S121= | Silent (SNP) | VAF 24/436 reads (6%) | called by muse, mutect2
- AL353753.1 | n.515T>A | RNA (SNP) | VAF 28/216 reads (13%) | called by muse, mutect2, varscan2
- DGKB | c.2126-31392A>G | Intron (SNP) | VAF 47/493 reads (10%) | called by muse, mutect2
- FGF23 | c.*5G>A | 3'UTR (SNP) | VAF 69/373 reads (18%) | catalogued as rs752559964, COSV52975259; called by muse, mutect2, varscan2
- IL20RA | c.579+31C>G | Intron (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- KCNMB2 | c.*281T>G | 3'UTR (SNP) | VAF 18/261 reads (7%) | catalogued as COSV64201026; called by muse, mutect2
- MIR6511A3 | chr16:16371546 C>T | 3'Flank (SNP) | VAF 106/3044 reads (3%) | catalogued as rs756822543; called by muse, mutect2
- MRPL49 | c.-23G>C | 5'UTR (SNP) | VAF 30/426 reads (7%) | called by muse, mutect2
- NDUFS7 | c.122+37G>C | Intron (SNP) | VAF 24/317 reads (8%) | called by muse, mutect2
- NKD1 | c.260-5512A>C | Intron (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- SLCO4A1 | chr20:62642120 G>A | 5'Flank (SNP) | VAF 54/323 reads (17%) | called by muse, mutect2, varscan2
- SYNE1 | c.-39A>C | 5'UTR (SNP) | VAF 202/872 reads (23%) | called by muse, mutect2, varscan2
